FM case AD4634 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/3c595273-c1c2-4eef-b784-4ae44db018db

Male, 23.6 years: Pituitary adenoma, NOS (ICD-O-3 8272/0) of the pituitary gland; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
